Gene-level copy-number profile of tumor specimen TCGA-3R-A8YX-01A from TCGA case TCGA-3R-A8YX, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 66.8 years (24,412 days).
Specimen TCGA-3R-A8YX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.4fb4becf-3826-4639-96d5-4fb2fd0fb550.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3R-A8YX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 822 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9dfca59c-1ea9-4ed4-9b59-be4dacde8c16

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 177; copy number 1: 2,938; copy number 2: 16,079; copy number 3: 25,637; copy number 4: 11,922; copy number 5: 1,830; copy number 6: 498; copy number 7: 88; copy number 8: 288; copy number 9: 17; copy number 10: 21; copy number 11: 37; copy number 12: 52; copy number 14: 34; copy number 15: 30; copy number 16: 58; copy number 18: 8; copy number 21: 24; copy number 22: 9; copy number 23: 8; copy number 27: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3R-A8YX-01A-11D-A37B-01): tumor purity 0.48, ploidy 6.24, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 177 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,178,605, 43 genes: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3.
- chr5:2,184,710–4,147,429, 18 genes: Y_RNA, AC092266.1, LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017, IRX1, AC016595.1, AC025773.1, AC025187.1, LINC02063.
- chr9:11,618,496–14,910,995, 38 genes: AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235, AL158157.1, LINC00583, PES1P2, AL360089.1, RPL3P11, ATP5PDP3, NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:14,921,337–15,019,729, 2 genes: LDHAP4, AL592293.1.
- chr9:15,163,622–15,362,134, 2 genes (within-gene range 0–1): TTC39B, RPL7P33.
- chr9:19,789,179–22,824,213, 72 genes (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 720 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:45,226,286–45,895,970, 5 genes, copy number 7: AC116350.1, HCN1, AC117529.2, AC117529.1, AC122694.1.
- chr8:36,764,445–37,406,724, 9 genes, copy number 7: RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2.
- chr8:37,983,070–40,897,833, 64 genes, copy number 7–8 (within-gene range 5–8) (broad region; genes not listed).
- chr9:1,977,784–7,598,377, 104 genes, copy number 7–23 (broad region; genes not listed).
- chr9:8,314,246–10,632,203, 12 genes, copy number 7–11 (within-gene range 7–17): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1.
- chr9:25,579,657–30,800,746, 48 genes, copy number 8–11: AL353730.1, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.2, AL162388.1, AL353684.1, AL354676.1, ME2P1, LINC01242, SLC4A1APP1, CDRT15P5, RBMXP2, KRT18P66, KRT18P36.
- chr11:55,537,002–56,234,255, 53 genes, copy number 8: OR4C14P, OR4C15, OR4C16, OR4C11, OR4P4, OR4S2, OR4C6, OR4V1P, OR4P1P, AP006437.1, OR5D2P, OR5D3P, OR5D17P, OR5D13, OR5D15P, OR5D14, OR5L1, OR5D18, OR5L2, OR5D16, OR9M1P, AC036111.2, AC036111.3, AC036111.1, TRIM51, OR5W1P, OR5W2, OR5I1, OR10AF1P, OR10AK1P, OR10AG1, OR7E5P, OR5F1, OR5F2P, OR5AS1, OR5AQ1P, OR5J1P, OR5BE1P, OR8I2, OR8I4P, OR8H2, OR5BN2P, OR8H3, OR5BN1P, OR8J3, OR8K4P, OR8K5, OR5J7P, OR5J2, OR8V1P, AC022882.1, OR8J2, OR5T2.
- chr11:65,695,552–67,873,367, 141 genes, copy number 8 (within-gene range 2–8) (broad region; genes not listed).
- chr11:68,891,276–71,818,238, 85 genes, copy number 7–12 (within-gene range 2–12) (broad region; genes not listed).
- chr12:57,738,013–59,064,238, 33 genes, copy number 9–15 (within-gene range 3–15): TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388, LRIG3, AC068305.2, RPS6P22.
- chr12:61,231,159–62,279,150, 7 genes, copy number 12–14 (within-gene range 3–14): AC090017.1, DUX4L52, AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6.
- chr12:62,965,325–63,360,037, 9 genes, copy number 22 (within-gene range 6–22): RPL14P1, AC078814.2, LDHAL6CP, AC078814.1, RSL24D1P5, AVPR1A, AC135584.1, HNRNPA1P69, AC026116.1.
- chr12:65,466,820–65,966,291, 10 genes, copy number 10–18 (within-gene range 3–18): AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1.
- chr12:66,347,431–67,069,162, 1 gene, copy number 8 (within-gene range 3–8): GRIP1.
- chr12:66,950,754–71,586,310, 92 genes, copy number 8–27 (within-gene range 3–27) (broad region; genes not listed).
- chr12:71,835,034–72,186,618, 5 genes, copy number 12–18 (within-gene range 2–18): AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1.
- chr12:73,648,666–74,402,600, 10 genes, copy number 8 (within-gene range 3–8): AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1.
- chr12:74,728,038–75,390,928, 9 genes, copy number 7: AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:76,721,534–76,880,352, 5 genes, copy number 8: RPL7P43, AC093014.1, ZDHHC17, CSRP2, AC124784.1.
- chr12:82,673,070–82,686,632, 1 gene, copy number 23 (within-gene range 7–23): AC091214.1.
- chr17:52,390,515–52,535,701, 1 gene, copy number 9: LINC01982.
- chr17:60,677,453–61,392,838, 1 gene, copy number 10 (within-gene range 4–10): BCAS3.
- chr17:61,034,636–61,863,528, 14 genes, copy number 10: AC005884.1, AC005884.2, RPL23AP74, AC005856.1, AC005746.3, AC005746.2, AC005746.1, TBX2-AS1, TBX2, LINC02875, TBX4, AC005901.1, NACA2, BRIP1.
- chr17:61,874,084–61,874,182, 1 gene, copy number 10: Y_RNA.

Autosomal genes at a single copy (total copy number 1): 2,066. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
